Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADBU, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADBU-TTP1-A (FFPE Scrolls).

[page 1 of 12]
SURGICAL PATHOLOGY REPORT

****Addendum****

* Converted Case * This report may not match the original report format

Patient Name:

Accession #:

DOB:

Gender:

F

Date of Procedure:

+0

Med. Rec. #:

Location:

Date Received:

+0

Physician(s):

Financial #:

FINAL PATHOLOGIC DIAGNOSIS:

LOW GRADE MALIGNANT GASTROINTESTINAL STROMAL TUMOR, INVOLVING
PELVIS AND OMENTUM AND RIGHT PERICOLIC GUTTER (SEE DESCRIPTION).

MEDICAL RECORD

Electronically Signed Out

Specimen:

- 1: PELVIC MASS
- 2: PELVIC MASS
- 3: PELVIC MASS
- 4: PELVIC MASS AND SKIN SCAR

Gross Description:

Multiple specimens are received. The first specimen is labelled "biopsy". It consists of small fragments of soft grey-tan tissue measuring 2 x 1 x 0.4 cm. A portion is submitted for frozen section and has the above frozen section diagnosis. It is totally embedded labelled FS-1. The rest of the material is totally embedded labelled A.

The second specimen is labelled "pelvic mass". It consists of a mass which is multilobulated and has a grey to purple coloration. It is quite soft to palpation. It measures 13 x 8 x 7 cm. Frozen section is performed and has the above frozen section diagnosis. Frozen section is submitted labelled FS-1. Additional representative material is submitted and labelled B-F.

The third specimen is labelled "pelvic mass". It consists of a mass lesion which is multilobulated and grey in color and soft. Cut section shows a soft cephalad appearing tumor mass. It measures 14 x 10 x 9 cm. Representative material is submitted labelled G,H,I and J.

The fourth specimen is submitted and labelled "skin scar". It consists of skin, with scar. It also contains multiple small fragments of cephalad soft tissue aggregating to 3 x 3 x 2 cm. Representative material is submitted labelled L.

[page 2 of 12]
Microscopic Description:

Microscopic sections show a proliferation of oval-to-spindled cells. The lesion is moderately cellular. There is moderate variation in nuclear size and shape. The cells have abundant pink cytoplasm. The cells in some areas have a whorled architectural pattern. Scattered lymphocytes are present throughout the tumor. Only occasional mitotic figures are present, with mitoses to 3 in 10 high power fields. I do not see tumor necrosis. The tumor has a very unusual microscopic pattern. Consideration is given to follicular dendritic cell tumor, and a low grade malignant gastrointestinal stromal tumor (extragastrointestinal). The following immunoperoxidase stains are performed: S-100, desmin, actin, CD-34, GFAP, melanin-A, HMB-45, EMA, CD-23, synaptophysin, chromogranin; all negative. Because of these negative reactions, I have sent tissue blocks to [REDACTED] for immunoperoxidase stains for CD-21 and CD-34 which are markers for follicular dendritic cell tumors. By telephone report, these markers are negative. However, they have also performed CD-117 (C-kit) and vimentin which are positive. CD-117 and vimentin are typically positive in gastrointestinal stromal tumors. Most gastrointestinal stromal tumors also show reactivity for CD-34 which is negative in this particular case. However, there is a population of these tumors which do not express CD-34. In my opinion the finding of a positive CD-117 in this case supports this tumor being a primary gastrointestinal stromal tumor, probably primary in the mesentery and/or omentum. Because of the unusual nature of this tumor I am also sending blocks to [REDACTED] for his opinion which will be added as an addendum when it is received.

Clinical Diagnosis:

Pre-op diagnosis: uterine myomas.

Frozen Section Diagnosis:

1. 2. AND 3. LOW-GRADE PROBABLY MALIGNANT NEOPLASM INVOLVING PERITONEAL CAVITY, FINAL DIAGNOSIS PENDING PERMANENT SECTIONS.

Procedure(s)/Addendum

Addendum

Addendum

*TEST PERFORMED BY [REDACTED], THEIR [REDACTED]

BODY SITE: Abdomen, NOS.

Clinical Data: [REDACTED] female with pelvic and abdominal mass.
Pdx: follicular dendritic cell tumor. Pathology report received.
Additional information received.

ANTIBODY/TESTS	MARKER FOR	RESULTS
CD35	Dendritic cells(C3b receptor)	negative
CD21	Dendritic cells (C3d receptor)B-cells	negative
CD117	Myeloid and Mast cells, GIST	positive

[page 3 of 12]
MRN:
Patient Name:
Date of Birth:

Requesting Physician:
Accession Number:
Exam Date:

Exam(s):
Exam Status: **Final**

IMPRESSION:

Visit #

XRAY DATE: +124
01

PROCEDURES: CT ABDOMEN ENHANCED +124

CT OF THE ABDOMEN: +124

REASON FOR EXAM: Gastric carcinoma.

HISTORY: female with questionable gastric carcinoma.

PROCEDURE:

Utilizing the gastric protocol with oral contrast and water, axial contiguous 5 mm thick sections were available throughout the abdomen during the injection of 150 cc of Omnipaque 350. Decubitus views are also available. 1 mg of glucagon is administered during this examination.

FINDINGS:

Mild, dependent atelectasis is present in the posterior segment of the bilateral lobes of the lungs.

A 2 mm granuloma is present at the dome of the liver. A 2.2 x 1.2 cm, rounded, low density lesion is present posterior to the posterior

[page 4 of 12]
inferior right hepatic lobe. This lesion is highly suspicious for an implant. Mild nodularity is noted throughout the mesentery. A mild swirl pattern is noted in the enhancement of the venous drainage at the mesenteric root. These are best seen on images 111 to 128. The proximal small bowel is mildly dilated.

The stomach is well distended utilizing the gastric protocol with effervescent granules and Glucagon. No thickening is noted of the gastric wall.

Symmetric renal enhancement is noted bilaterally.

There is mild thickening of the distal esophagus proximal to the gastroesophageal junction.

IMPRESSION:

1. Well-distended stomach utilizing the gastric protocol. There is no evidence of mass lesions throughout the stomach.

2. 2.2 x 1.2 cm, oval-shaped, soft tissue density mass posterior inferior right hepatic lobe. This is highly suspicious for tumor implantation.

3. Nodularity of the mesentery A swirl pattern is noted in the venous drainage at the mesenteric root. These findings may represent mild tumor infiltration within the mesentery. Follow up examination is suggested. The proximal small bowel mildly dilated and transient proximal small bowel volvulus is not excluded.

4. Mild thickening is noted of the distal esophagus proximal to the gastroesophageal junction. Correlation with endoscopic findings is suggested for further analysis.

[page 5 of 12]
RADIOLOGIST:
ORDERING MD:

~

Signed by:

[page 6 of 12]
MRN:
Patient Name:
Date of Birth:

Requesting Physician:
Accession Number:
Exam Date:

Exam(s):
Exam Status: Final

IMPRESSION:
Visit #

XRAY DATE: +137

PROCEDURES: CT ABDOMEN PELVIS ENHANCED +137

CT OF THE ABDOMEN AND PELVIS +137

CLINICAL DATA: female with gastric carcinoma.

TECHNIQUE:

Multiple contiguous axial images were obtained from the lung bases to below the symphysis pubis following the administration of oral contrast and 150 cc of intravenous Omnipaque.

COMPARISON: +124

FINDINGS:

The visualized lung bases are unremarkable.

A 3 mm granuloma is again seen within the dome of the right lobe of the liver. The liver is normal in size and there is no intrahepatic biliary dilatation. The spleen, pancreas, adrenals, and gallbladder are unremarkable. A 7 mm nodule is seen along the inferior border of the spleen, suggestive of a tiny splenule.

The kidneys demonstrate prompt, symmetric nephrograms. A few subcentimeter lymph nodes are seen in the retroperitoneal periaortic and aortocaval region, measuring up to 4 mm.

A 2 x 1.8 cm cyst is seen arising from the right ovary. A small amount of fluid is seen within the cul-de-sac that is likely physiologic in nature. The urinary bladder is unremarkable. A few tiny nodes are seen in both inguinal fossa, measuring up to 8 mm.

A 2.2 x 0.8 cm low density ovoid mass is seen immediately lateral to the inferior right lobe of the liver. This finding is of indeterminate etiology, but may represent a focal tumor implant. Minimal nodularity of the mesentery is again seen which is indeterminate in nature, but may represent tumor involvement.

Mild thickening of the distal esophagus at the GE junction is again

[page 7 of 12]
seen, which may represent tumor involvement. Clinical correlation is advised.

IMPRESSION:

1. Mild circumferential thickening is seen involving the distal esophagus and GE junction. These findings are of uncertain etiology, but may represent tumor involvement or esophagitis. Clinical correlation is advised.
2. Small ovoid hypodense lesion is seen adjacent to the inferior aspect of the posterior segment of the right lobe. This finding is of uncertain etiology, but may represent tumor implant. Clinical correlation is advised.
3. Subcentimeter retroperitoneal adenopathy.
4. Right adnexal cyst, likely physiologic in nature.
5. A small amount of fluid is seen within the cul-de-sac.

Addendum:

+62

The outside prior film, dated [REDACTED] is now available for comparison.

7mm nodule seen along the inferior border of the spleen is stable in size. This may represent a splenule.

Soft tissue density consistent with a tumor implant seen between the liver tip and right kidney demonstrates interval decrease in size. A second smaller density located more anteriorly has resolved entirely.

Soft tissue nodule anterior to the right gonadal vein in the right lower quadrant on image #38, is stable compared with prior examination.

Previously noted density posterior to the uterus is still seen on the current examination but resembles fluid rather than tumor implant.

There has been interval resolution of fluid collection behind the right rectus muscle.

RADIOLOGIST: [REDACTED]
ORDERING MD: [REDACTED]

Dictated:
Transcribed:
Last Edited:
Revised:
Finalized:

[page 8 of 12]
[REDACTED]

MRN: [REDACTED]
Patient Name: [REDACTED]
Date of Birth: [REDACTED]

Requesting Physician: [REDACTED]
Accession Number: [REDACTED]
Exam Date: [REDACTED]

Exam(s):
Exam Status: Final

IMPRESSION:

Visit # [REDACTED]

XRAY DATE: [REDACTED] +222

PROCEDURES: CT CHEST/ABD/PELVIS ENHANCED [REDACTED] +222

CT CHEST, ABDOMEN, AND PELVIS [REDACTED] +222

COMPARISON: Comparison is made to previous examinations dated [REDACTED] and [REDACTED] +137

CLINICAL DATA: [REDACTED] female with gastric carcinoma.

TECHNIQUE:

Contiguous 7 millimeter transaxial images of the chest, abdomen, and pelvis were obtained following oral contrast and intravenous administration of Omnipaque 350. Routine gastric protocol as well as decubitus images were performed.

FINDINGS:

The lungs are clear bilaterally. No pulmonary nodules or hilar or mediastinal adenopathy. No pleural or pericardial effusion. The heart is normal in size and configuration.

Mild circumferential thickening of the GE junction wall and posterior wall of the gastric antrum may represent inflammatory changes, although tumor involvement is not excluded and clinical correlation is suggested. The remainder of the GI tract is unremarkable.

Previously identified hypodense lesion adjacent to the inferior aspect of the posterior segment of the right lobe of the liver is not visualized on the current examination. The liver is homogeneous in attenuation without a focal discrete mass. A small hepatic calcified granuloma at the dome is stable. The pancreas, gallbladder, both adrenal glands, and both kidneys are within normal limits. A small accessory splenule is stable. The spleen is normal. No new adenopathy within the abdomen or pelvis. Subcentimeter mesenteric lymph nodes persist.

Mild amount of free fluid is within the pelvis. A 3.6 x 2.7 centimeter right adnexal hypoattenuating mass may represent a

[page 9 of 12]
follicular cyst. No other adnexal abnormality. The uterus is heterogeneous which may represent multiple leiomyomas. Prominence of pelvic vasculature is suggestive of pelvic varices. The bladder is normal.

Musculoskeletal structures are within normal limits. No focal lytic or blastic lesions within the bones.

IMPRESSION:

+137

1. In comparison to the previous examination of [REDACTED] there is overall improvement without definite evidence of distant metastases.
2. Mild circumferential thickening of the gastroesophageal junction wall and posterior wall of the gastric antrum may be related to inflammatory changes (i.e., gastritis). However, tumor involvement is not excluded and clinical correlation is recommended.
3. No new adenopathy or mass lesion within the chest, abdomen, or pelvis.
4. Right adnexal cystic mass likely representative of a follicular cyst, now measuring up to 3.6 centimeters in maximal diameter. Recommend follow-up examination with ultrasound to evaluate for regression or progression. Mild free fluid within the pelvis.

RADIOLOGIST: [REDACTED]
ORDERING MD: [REDACTED]

~
Dictated:
Transcribed: [REDACTED]
Last Edited:
Revised:
Finalized:

[page 10 of 12]
[REDACTED]

MRN: [REDACTED]
Patient Name: [REDACTED]
Date of Birth: [REDACTED]

Requesting Physician: [REDACTED]
Accession Number: [REDACTED]
Exam Date: +4137

Exam(s): **MR ABDOMEN WITH AND WITHOUT CONTRAST, PELVIS WITH CONTRAST**
Exam Status: **Final**

MR ABDOMEN UN/EN PELVIS ENH [REDACTED] +4137

COMPARISON: Outside CT examinations dated [REDACTED]
and [REDACTED] +4095, +4052

CLINICAL HISTORY: [REDACTED] female with history of pelvic
GIST, initially resected in [REDACTED] with pelvic recurrence noted in
[REDACTED]

+3346

TECHNIQUE: Multiplanar T1 and T2 weighted, diffusion and dynamic
post-gadolinium images were obtained through the abdomen and
pelvis on a 1.5 Tesla magnet.

FINDINGS:

Liver: Unremarkable

Gallbladder: Unremarkable

Spleen: Subcentimeter cyst in the superior pole of the spleen
noted, dilation for stability limited by differences in
modalities and format of prior exams.

Pancreas: Unremarkable

Adrenal Glands: Unremarkable

Kidneys: Unremarkable

GI Tract: Unremarkable

Pelvis: Within the right pelvis there is a solid and cystic 9.0 x
8.6 x 7.0 cm mass, appears very closely associated with the broad
ligament with multiple loops of adjacent bowel, uterus, and
pelvic iliac vessels noted. Aside from suspected involvement
with the broad ligament, no definite invasion of the adjacent
structures. There is an additional 2.1-cm similar appearing
solid and cystic lesion just lateral to the dominant mass
anteriorly, reference series 16, image 39. Large pelvic draining
vessels the region of the mass, especially anteriorly and
laterally, likely draining into the right external iliac vessels.

The right ovary is not clearly seen. The left ovary is within
normal limits. The uterus is unremarkable.

Lymphadenopathy: Absent. MRI limited for evaluation of small
abdominopelvic implants.

Ascites: Absent

Bones: No suspicious lesions

[page 11 of 12]
IMPRESSION:

1. Large dominant solid and cystic 9.0-cm mass in the right hemipelvis, closely associated with the broad ligament and involvement of the broad ligament is not excluded. Mass is adjacent to the uterus, multiple loops of bowel, and pelvic vessels without definite other involvement. Additional 2.1-cm solid cystic satellite lesion just lateral to the dominant mass noted.

2. Stability is difficult to evaluate due to technical differences from the prior examination this. No frank adenopathy or other mass seen.

END OF IMPRESSION:

Dictated: EXTERNAL R

+4137

Transcribed:

Last Edited: EXTERNAL R

Revised: EXTERNAL R

Finalized: EXTERNAL R

[page 12 of 12]
SURGICAL PATHOLOGY REPORT

****Addendum****

* Converted Case * This report may not match the original report format

Patient Name: [REDACTED]

Accession #:

DOB: [REDACTED]

Gender: F

Date of Procedure:

Med. Rec. #: [REDACTED]

Location:

Date Received:

Physician(s):

Financial #:

FINAL PATHOLOGIC DIAGNOSIS:

LOW GRADE MALIGNANT GASTROINTESTINAL STROMAL TUMOR, INVOLVING PELVIS AND OMENTUM AND RIGHT PERICOLIC GUTTER (SEE DESCRIPTION).

MEDICAL RECORD

Electronically Signed Out

Specimen:

- 1: PELVIC MASS
- 2: PELVIC MASS
- 3: PELVIC MASS
- 4: PELVIC MASS AND SKIN SCAR

1CB-0-3

Primary: gastrointestinal stromal tumor, malignant
8936/3

Gross Description:

Multiple specimens are received. The first specimen is labelled "biopsy". It consists of small fragments of soft grey-tan tissue measuring 2 x 1 x 0.4 cm. A portion is submitted for frozen section and has the above frozen section diagnosis. It is totally embedded labelled FS-1. The rest of the material is totally embedded labelled A.

Site: abdomen, NOS C76.2

1CB-10

C76.2 abdomen primary

The second specimen is labelled "pelvic mass". It consists of a mass which is multilobulated and has a grey to purple coloration. It is quite soft to palpation. It measures 13 x 8 x 7 cm. Frozen section is performed and has the above frozen section diagnosis. Frozen section is submitted labelled FS-1. Additional representative material is submitted and labelled B-F.

The third specimen is labelled "pelvic mass". It consists of a mass lesion which is multilobulated and grey in color and soft. Cut section shows a soft cephalad appearing tumor mass. It measures 14 x 10 x 9 cm. Representative material is submitted labelled G, H, I and J.

hw
5/26/10

The fourth specimen is submitted and labelled "skin scar". It consists of skin, with scar. It also contains multiple small fragments of cephalad soft tissue aggregating to 3 x 3 x 2 cm. Representative material is submitted labelled L.

Source: NCI Genomic Data Commons file a64c0417-d306-4b60-95f1-ecce7e35b619 (ER0214 ER-ADBU Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).